Gene-level copy-number profile of tumor specimen CDDP-ACIT-TTP1-A from CDDP_EAGLE case CDDP-ACIT, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73 years.
Specimen CDDP-ACIT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aac26aa3-15c2-48bb-8386-1c2ed65999f2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACIT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,737 have no estimate.
https://portal.gdc.cancer.gov/files/45943ada-1f47-4453-bbce-d2bd58f4f0a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,259; copy number 2: 54,126; copy number 3: 1,440; copy number 4: 26; copy number 5: 32; copy number 7: 1; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 35 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:40,020,240–40,021,517, 1 gene, copy number 8: KRT18P25.
- chr9:136,647,872–136,660,421, 1 gene, copy number 5 (within-gene range 2–5): AL590226.1.
- chr15:21,405,401–21,981,245, 30 genes, copy number 5: POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P.
- chr16:28,802,743–28,817,828, 1 gene, copy number 5 (within-gene range 2–5): AC145285.2.
- chr22:21,341,595–21,358,067, 2 genes, copy number 7–8: PPP1R26P5, LINC01651.

Autosomal genes at a single copy (total copy number 1): 403. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
